Surgical pathology report (de-identified scan), TCGA case TCGA-77-A5G7, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-A5G7-01B (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, squamous
cell 8670/3

Site: Lung, upper lobe
(34.1)

yo 2/8/13

Histopathology Report

HISTORY

No clinical notes supplied.

MACROSCOPIC

One specimen submitted.

The specimen is labelled 'left upper lobe' and consists of a lobe of lung measuring 230 x 100 x 20 mm in the uninflated state. A number of bullous structures are present at the apex of the lobe over an area 40 x 20 mm. There is a small area of fibrous pleural thickening on the lateral aspect of the lobe over an area approximately 20 x 20 mm. Beneath this area of thickening is a palpable tumour mass. The pleura moves over this mass and does not appear to be involved. At the hilum there are two bronchial profiles, 10 and 8 mm in diameter. Very few peribronchial nodes are included. A stapled resection line, 70 mm in length, extends posteroinferiorly from the hilum. Transverse slicing reveals an extensively necrotic tumour mass 25 x 25 x 20 mm, lateral to the hilum and approaching the lateral pleural surface. The cut surface of this tumour has a variegated grey and yellow appearance. Adjacent to the tumour is an ill defined area of yellowish discolouration of lung parenchyma measuring approximately 10 mm in maximum dimension. There is also an ill-defined area of parenchymal fibrosis adjacent to the tumour. Elsewhere the lung parenchyma shows severe emphysematous changes. [1A, bronchial resection margin; 1B, peribronchial lymph nodes; 1C-1E tumour with overlying pleura; 1F, area of yellowish discolouration; 1G, ill-defined fibrous scar adjacent to tumour; 1H, apical bulla; 1I, uninvolved lung parenchyma superior to tumour; 1J, involved lung parenchyma inferior to tumour.]

MICROSCOPY

Sections show moderately differentiated squamous cell carcinoma measuring 25mm in maximum dimension. There is extensive tumour necrosis with associated foamy macrophages and cholesterol clefts. The periphery of the carcinoma has a growth pattern filling air spaces. Extensive vascular invasion is present at the periphery of the carcinoma together with focal perivascular lymphatic space invasion. There is mild fibro-elastotic scarring of the visceral pleura adjacent to the tumour but no evidence of pleural invasion by the carcinoma. The carcinoma is clear of the bronchial resection margin which shows focal squamous metaplasia and mild squamous dysplasia. The area of yellow discoloration adjacent to the carcinoma shows focal collapse, interstitial fibrosis and localised obstructive changes including dilated air spaces containing numerous macrophages and proteinaceous fluid. Within this region there is a mildly dilated bronchiole showing focal moderate squamous dysplasia. There is also an area of dense fibrous scarring adjacent to the carcinoma. The non-neoplastic lung shows scattered mixed dust macules and aggregates of pigmented airspace macrophages. Apical bullous emphysema is present and this is associated with subpleural fibrosis and prominent chronic inflammation together with focal fibrous obliteration of the pleural space and a small amount of

[page 2 of 2]
adherent chest wall fat. The peribronchial lymph nodes show sinus histiocytosis and mild carbon pigment deposition but no evidence of malignancy.

SUMMARY

Left upper lobe:

Moderately differentiated squamous cell carcinoma (25mm maximum dimension)

Extensive vascular invasion present; focal lymphatic invasion present

Squamous metaplasia with mild dysplasia present at bronchial resection margin

No pleural invasion

No peribronchial lymph node involvement

Peritumoral scar and obstructive changes

Apical bullous emphysema with fibrosis and focal fibrous adhesion obliterating the pleural space

Pathologic stage: T1 N0

reported

T-28000 M-80703

	ANATOMICAL PATHOLOGY
--	----------------------

Source: NCI Genomic Data Commons file 68cf7608-591f-487e-8eca-c2263f5f33fe (TCGA-77-A5G7.966AA667-7891-45FF-BD1F-9172455B57C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).